Somatic mutation profile of tumor specimen TCGA-QR-A6GR-01A (aliquot TCGA-QR-A6GR-01A-11D-A35D-08) from TCGA case TCGA-QR-A6GR, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 30.4 years (11,089 days).
Specimen TCGA-QR-A6GR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d38becf2-b03b-41e1-a47f-4f232765261c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A6GR-10A (Blood Derived Normal), aliquot TCGA-QR-A6GR-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c825970-1315-4d33-a9c1-5c0edbe22cae

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 2, Intron 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFDN | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.743); catalogued as rs764123133, COSV60045170; called by muse, mutect2, varscan2
- DNAH8 | c.9209-1G>A p.X3070_splice | Splice Site (SNP) | VAF 13/51 reads (25%) | catalogued as rs781195067, COSV59457478; called by muse, mutect2, varscan2
- MAL | c.220A>G p.I74V | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as rs1189857522, COSV59431344; called by muse, mutect2
- CKAP5 | c.6068G>T p.R2023I (on ENST00000529230 / NM_001008938.4; = p.R1963I on NM_014756.3) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- GANC | c.1210G>A p.G404S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- ITSN1 | c.1712C>G p.A571G | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- MAL | c.218A>G p.Y73C | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RALGAPB | c.1741G>A p.V581M | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- SLFN11 | c.2131G>C p.D711H | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TGM5 | c.1577T>C p.V526A (on ENST00000220420 / NM_201631.4; = p.V444A on NM_004245.4) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.84); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- WWP1 | c.2414A>G p.Q805R | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASB12 | c.102G>A p.E34= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as rs1042326063, COSV62855968; called by muse, mutect2
- POTEA | c.156C>T p.S52= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as rs1408164833; called by muse, mutect2, varscan2
- BABAM2 | c.1089-11139G>A | Intron (SNP) | VAF 26/75 reads (35%) | catalogued as rs1399473497; called by muse, mutect2, varscan2
- XIRP2 | c.*1107T>A | 3'UTR (SNP) | VAF 15/43 reads (35%) | catalogued as rs765547541; called by muse, mutect2, varscan2
